Surgical pathology report (de-identified scan), TCGA case TCGA-GL-A9DE, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-GL-A9DE-01A (Primary Tumor).

[page 1 of 2]
ICD O-3
Carcinoma, papillary renal cell 826013
Site @ Kidney NOS 064.9
3/13/14

Operative Procedure:
Right laparoscopic nephrectomy

Specimen Received:
Right kidney

Final Pathologic Diagnosis:
Kidney, right, laparoscopic nephrectomy:

Tumor histologic type: Papillary renal cell carcinoma, type 2
Sarcomatoid features (%): Not identified
Tumor size: 4.8 cm (greatest dimension)
Other dimensions: 3.7 x 3.5 cm
Macroscopic extent of tumor: Confined to the kidney
Focality: Unifocal
Number of tumors: 1
Fuhrman grade: 3 of 4
Microscopic extent of tumor:
Perinephric fat invasion: No
Renal sinus invasion: No
Other: Not identified
Renal vein involvement: No
Adrenal gland present: No
(If yes) Involved by tumor: Not applicable
(If yes) Direct invasion or metastasis: Not applicable
Cancer at resection margin: No
(If yes) Location(s): Not applicable
Pathologic findings in nonneoplastic kidney: Renal cortical cyst
Renomedullary interstitial cell tumor
Hilar lymph nodes present: Not identified
(If yes) Number involved/number present: Not applicable

Pathologic stage (2010) pT1b pNx pM-not applicable

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

The specimen is received in formalin labeled with the patient name and additionally labeled, "right kidney" and consists of a kidney received with abundant perinephric fibroadipose tissue. The kidney has dimension of 11.5 x 7 x 5 cm. The attached ureter has a length of 5 cm and diameter of 0.4 cm. The specimen is received partially inked and partially incised. Sectioning through the specimen reveals a tan-brown, lobulated, fairly well-delineated mass in the mid portion of the kidney that has dimensions of 4.8 x 3.7 x 3.5 cm. This mass involves the renal sinus fat, focally abuts the wall at the renal vein and

[page 2 of 2]
focally extends to the renal capsule. The mass does not appear to extend beyond the renal capsule. The mass has a hemorrhagic, degenerative cut surface. A portion of the mass has been submitted to the Tissue Bank. Adjacent to the mass is a cortical cyst that is 0.8 cm in greatest dimension that contains tan-brown fluid. The cyst lining is predominately smooth. There is a tan-white, well-delineated nodule that is 1.2 cm from the mass that has dimensions of 0.3 x 0.2 x 0.2 cm. The remaining, uninvolved renal parenchyma is pink-tan to red-brown with a fairly well-delineated corticomedullary junction. The thickness of the cortex is up to 1.2 cm. The collecting system is lined by pink-tan, granular mucosa. The capsule strips with some difficulty revealing a red-brown to pink-tan, nodular surface.

The hilar fat is removed and has a weight of 15 g. Sectioning reveals no definitive lymph nodes.

Representative sections are submitted as follows:

- 1 hilar margins en face;
- 2,3 mass to inked external surface;
- 4 mass to capsule;
- 5 mass to renal sinus fat;
- 6 mass to renal sinus fat and wall of renal vein;
- 7 mass to uninvolved kidney;
- 8 cortical cyst adjacent to mass;
- 9 well-delineated nodule adjacent to mass;
- 10 uninvolved renal parenchyma;
- 11,12 hilar fat for possible lymph node capture.

Please note, multiple gross photographs are taken. Also there is no adrenal gland present.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Surgical Pathology Report

Taken: DOB: Age: Gender: M

hw 12/17/13		Yes	No
Criteria			

Source: NCI Genomic Data Commons file c0ab451a-50b9-4f8d-8cd0-a87eabd83a4b (TCGA-GL-A9DE.9E443ECF-C8CE-4AB7-ACF6-D64C50F661BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).